Somatic mutation profile of tumor specimen TCGA-A6-2684-01A (aliquot TCGA-A6-2684-01A-01D-A270-10) from TCGA case TCGA-A6-2684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-A6-2684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 533d93d4-806d-4e71-ac5b-ecbaa0e4dbc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2684-10A (Blood Derived Normal), aliquot TCGA-A6-2684-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c784ff87-05ee-4617-9e98-fe73b9069553

The open-access MAF lists 121 somatic variants for this specimen: 88 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 32, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 2, Splice Region 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1620dup p.Q541Tfs*19 | Frame Shift Ins (INS) | VAF 117/238 reads (49%) | catalogued as rs1131691555, CI040932, CI106503, COSV57342389; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/195 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 44/133 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.211T>C p.F71L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs397507512, CM030494, CM056378, COSV61006422; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL5 | c.1879G>A p.G627R (on ENST00000354273; = p.G683R on NM_016234.3) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100634846; called by muse, mutect2, varscan2
- B4GALT1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101123019; called by muse, mutect2, varscan2
- BCHE | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52253199; called by muse, mutect2, varscan2
- CAPG | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs987498288, COSV99809651; called by muse, mutect2, varscan2
- CCDC17 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1326750378, COSV51973854; called by muse, mutect2, varscan2
- CDC42BPG | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs1010178541, COSV61348540; called by muse, mutect2, varscan2
- CDH4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1035268864, COSV64646564; called by muse, mutect2, varscan2
- CLEC5A | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs151000385, COSV101407806; called by muse, mutect2, varscan2
- COL2A1 | c.3003G>A p.S1001= | Splice Region (SNP) | VAF 36/88 reads (41%) | catalogued as COSV100477014; called by muse, mutect2, varscan2
- CSMD1 | c.1693G>T p.V565F (on ENST00000520002; = p.V564F on NM_033225.6) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59300299, COSV59359418; called by muse, mutect2, varscan2
- DARS2 | c.1879A>C p.K627Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV53409652; called by muse, mutect2, varscan2
- DMPK | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.914); catalogued as rs373703629, COSV52176405; called by muse, mutect2, varscan2
- DMRTA1 | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV57925582; called by muse, mutect2, varscan2
- DNAH11 | c.9458C>G p.T3153S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100181312; called by muse, mutect2, varscan2
- DNAH7 | c.10376G>T p.S3459I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV100418091; called by muse, mutect2, varscan2
- DNER | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs549129843, COSV59159704, COSV59170885; called by muse, mutect2, varscan2
- DOCK6 | c.5045G>A p.G1682E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99626917; called by muse, mutect2, varscan2
- EIF2AK3 | c.2582C>A p.T861N | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.82); catalogued as rs1456637620, COSV100304211; called by muse, mutect2
- EPHA2 | c.1308G>C p.Q436H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100626345; called by muse, mutect2, varscan2
- EXOC6B | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs755302023, COSV55564876; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FAM83C | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100981746; called by muse, mutect2
- FAM9A | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.923); catalogued as COSV101121378; called by muse, mutect2, varscan2
- FAN1 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100756118; called by muse, varscan2
- FOLR3 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100281896; called by muse, mutect2, varscan2
- FRMD6 | c.688G>A p.A230T (on ENST00000344768 / NM_001267046.2; = p.A222T on NM_152330.4) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs374236968; called by muse, mutect2, varscan2
- GALNS | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV99243531; called by muse, mutect2, varscan2
- IRF2BP1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1038526208, COSV100139044; called by muse, mutect2, varscan2
- KCNV2 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773122223, COSV66055593; called by muse, mutect2, varscan2
- KLHL34 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs914654948, COSV101070016; called by muse, mutect2, varscan2
- LDOC1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.172); catalogued as COSV65159498; called by muse, mutect2, varscan2
- LRRK1 | c.6034C>A p.R2012S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99443715; called by muse, mutect2, varscan2
- LURAP1L | c.205T>A p.L69M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV100070966; called by muse, mutect2, varscan2
- MAN1A2 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100741090; called by muse, mutect2, varscan2
- MAT2A | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM150092, COSV99290261; called by muse, mutect2, varscan2
- MCTS1 | c.430T>C p.C144R | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV64892953; called by muse, mutect2, varscan2
- MED15 | c.1814C>T p.P605L (on ENST00000263205 / NM_001003891.3; = p.P565L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53034231; called by muse, mutect2, varscan2
- MIA3 | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100719570; called by muse, mutect2, varscan2
- MKNK2 | c.655-1G>A p.X219_splice | Splice Site (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99170456; called by muse, mutect2, varscan2
- MPP4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772583255, COSV59628629; called by muse, mutect2, varscan2
- N4BP2L2 | c.1517C>G p.T506S | Missense Mutation (SNP) | VAF 127/432 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57230522; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- OCA2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769550106, COSV62353421, COSV62356115; called by muse, mutect2, varscan2
- OR5D14 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs200877014, COSV59455703; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDH11X | c.3455G>T p.C1152F | Missense Mutation (SNP) | VAF 87/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100015987; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56553142; called by muse, mutect2, varscan2
- PCDHA7 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV65343999; called by muse, mutect2, varscan2
- PHF20L1 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs375482501; called by muse, mutect2, varscan2
- PLXNA1 | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1395349765, COSV99302888; called by muse, mutect2, varscan2
- PPARGC1B | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1199093107, COSV100495276; called by muse, mutect2, varscan2
- PTPRS | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53627986; called by muse, mutect2, varscan2
- PWWP3A | c.985G>A p.G329R (on ENST00000627377; = p.G328R on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs767705392, COSV100262320; called by muse, mutect2, varscan2
- RHO | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs201008735, COSV56214488; called by muse, mutect2, varscan2
- RIOX2 | c.849C>G p.D283E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV57725087; called by muse, mutect2, varscan2
- ROPN1B | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 100/438 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV99305718; called by muse, mutect2, varscan2
- RYR1 | c.6083G>A p.R2028Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.341); catalogued as rs747050942, COSV62103723; called by muse, mutect2, varscan2
- SETDB1 | c.2828C>T p.T943I | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs966900297, COSV99646030; called by muse, mutect2, varscan2
- SHROOM2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254465222, COSV101099156; called by muse, mutect2, varscan2
- SIN3B | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV99932133; called by muse, mutect2, varscan2
- SPAG6 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs918860729, COSV57620478; called by muse, mutect2, varscan2
- SPTY2D1 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100311885; called by muse, mutect2, varscan2
- TBX3 | c.126del p.A43Rfs*2 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs746244654; called by mutect2, pindel, varscan2
- TCF12 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 56/172 reads (33%) | catalogued as COSV51003399, COSV51030204; called by muse, mutect2, varscan2
- TEPSIN | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330024; called by muse, mutect2, varscan2
- TIAM1 | c.3880T>C p.F1294L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99739570; called by muse, mutect2, varscan2
- TMEM47 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as COSV52063432; called by muse, mutect2, varscan2
- TMEM63C | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161204403, COSV100029576; called by muse, varscan2
- TMOD2 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs779836040, COSV51044039, COSV51044309; called by muse, mutect2, varscan2
- TNRC6B | c.1516G>T p.V506F | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1412700883, COSV57309595; called by muse, mutect2, varscan2
- TOGARAM1 | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100753333; called by muse, mutect2, varscan2
- TPD52L1 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59194389; called by muse, mutect2, varscan2
- TTBK1 | c.331-1G>A p.X111_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52497530; called by muse, mutect2, varscan2
- TTN | c.78193G>A p.E26065K (on ENST00000591111; = p.E18641K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | PolyPhen benign (0.046); catalogued as rs72648217, COSV59954756; called by muse, mutect2, varscan2
- UNC79 | c.7594G>C p.E2532Q (on ENST00000393151 / NM_001346218.2; = p.E2355Q on NM_020818.5) | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56387677, COSV56416140; called by muse, mutect2, varscan2
- ZHX2 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766810365, COSV100074047; called by muse, mutect2, varscan2
- ZNF512 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100179487; called by muse, mutect2, varscan2
- ZRANB1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV62844246; called by muse, mutect2, varscan2
- ZXDB | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs751291946, COSV100886087, COSV100886101; called by muse, mutect2, varscan2
- NBEAL1 | c.6215dup p.N2072Kfs*10 | Frame Shift Ins (INS) | VAF 37/113 reads (33%) | called by mutect2, varscan2
- SPATA31A3 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.829); called by mutect2, varscan2
- TGIF1 | c.419_422dup p.S142Vfs*61 (on ENST00000330513 / NM_001374396.1; = p.S162Vfs*61 on NM_003244.4) | Frame Shift Ins (INS) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- ASB9 | c.690T>C p.A230= | Silent (SNP) | VAF 60/255 reads (24%) | catalogued as COSV100995601; called by muse, mutect2, varscan2
- ATOH7 | c.267C>T p.I89= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV101028540; called by muse, mutect2, varscan2
- ATP4A | c.2697G>A p.A899= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs200535073, COSV52865580; called by muse, mutect2, varscan2
- C5orf49 | c.279G>A p.P93= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs368114686; called by muse, mutect2, varscan2
- CDH11 | c.27C>T p.A9= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as rs200930494, COSV51781373; called by muse, mutect2, varscan2
- CES3 | c.1581G>A p.L527= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV100310078; called by muse, mutect2, varscan2
- CLCN5 | c.210G>A p.S70= | Silent (SNP) | VAF 47/255 reads (18%) | catalogued as rs376292808, COSV100260449; called by muse, mutect2, varscan2
- CLDN19 | c.414G>A p.S138= | Silent (SNP) | VAF 65/166 reads (39%) | catalogued as rs370124717; called by muse, mutect2, varscan2
- CSAG2 | c.348C>T p.P116= | Silent (SNP) | VAF 231/1056 reads (22%) | catalogued as rs1259270518; called by muse, mutect2, varscan2
- CUX2 | c.4191G>A p.S1397= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs745631840, COSV99920993; called by muse, mutect2, varscan2
- EIF4G1 | c.4431G>A p.T1477= (on ENST00000346169 / NM_198241.3; = p.T1282= on NM_004953.5) | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs778504953, COSV100072387; called by muse, mutect2, varscan2
- FMN2 | c.3528G>A p.P1176= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs183336748, COSV60445930; called by muse, mutect2, varscan2
- FOXC2 | c.1323G>A p.A441= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs541894945, COSV100234427; called by muse, mutect2, varscan2
- HFM1 | c.2631G>A p.L877= | Silent (SNP) | VAF 75/246 reads (30%) | catalogued as COSV99647004; called by muse, mutect2, varscan2
- HSPG2 | c.9921C>T p.H3307= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs147560911; called by muse, mutect2, varscan2
- LRIT3 | c.1113G>A p.P371= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs181208057, COSV59986649; called by muse, mutect2, varscan2
- MYO18B | c.7614C>T p.G2538= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs373074703; called by muse, mutect2, varscan2
- NPLOC4 | c.288C>T p.G96= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs999612410, COSV58620484; called by muse, mutect2, varscan2
- NPM3 | c.54G>A p.T18= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100761987; called by muse, mutect2, varscan2
- NTRK3 | c.1824C>T p.G608= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs376552616; called by muse, mutect2, varscan2
- NUCKS1 | c.204C>G p.T68= | Silent (SNP) | VAF 114/319 reads (36%) | catalogued as COSV100900817; called by muse, mutect2, varscan2
- NUDT11 | c.477G>A p.S159= | Silent (SNP) | VAF 149/582 reads (26%) | catalogued as rs1557326605, COSV101047068; called by muse, mutect2, varscan2
- OSMR | c.1413T>C p.V471= | Silent (SNP) | VAF 79/290 reads (27%) | catalogued as COSV99953900; called by muse, mutect2, varscan2
- PFKFB1 | c.837C>T p.R279= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs749925058, COSV66627840; called by muse, mutect2, varscan2
- PRR22 | c.702G>T p.L234= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV57833925; called by muse, mutect2, varscan2
- RSPH6A | c.945C>T p.G315= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs778223516, COSV99680178; called by muse, mutect2, varscan2
- SCN1A | c.135C>T p.D45= | Silent (SNP) | VAF 57/184 reads (31%) | catalogued as rs201985242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SNX8 | c.366C>T p.H122= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99771229; called by muse, mutect2, varscan2
- SPIN2B | c.291A>G p.E97= | Silent (SNP) | VAF 38/172 reads (22%) | called by mutect2, varscan2
- TRIM56 | c.1887G>A p.K629= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100047862; called by muse, mutect2
- VCX2 | c.414C>T p.T138= | Silent (SNP) | VAF 101/466 reads (22%) | catalogued as rs757658111, COSV57704763; called by muse, mutect2, varscan2
- ZNF536 | c.3144G>A p.A1048= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1280150294, COSV62832577; called by muse, mutect2, varscan2
- AKT2 | c.-85+2548A>G | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100845508; called by muse, mutect2, varscan2
